Somatic mutation profile of tumor specimen C3N-03783-01 (aliquot CPT0245730006) from CPTAC case C3N-03783, project CPTAC-3 (Gum — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 67.1 years (24,500 days).
Specimen C3N-03783-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Alveolar Ridge; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a62b338-1224-4eba-9f31-934e85540f45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03783-31 (Blood Derived Normal), aliquot CPT0245770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c896c955-e40f-421f-9f93-ceee9b14369d

The open-access MAF lists 140 somatic variants for this specimen: 102 protein-altering or splice-affecting, 27 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 27, RNA 3, Nonsense Mutation 3, Frame Shift Del 3, 3'Flank 3, In Frame Del 2, Intron 2, Splice Region 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.613T>G p.Y205D | Missense Mutation (SNP) | VAF 103/442 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 48/462 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APBA2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1291789171, COSV68794329; called by muse, mutect2, varscan2
- ATP8B4 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs200106056, COSV52713293; called by muse, mutect2
- CCDC39 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV56490167, COSV99870496; called by muse, mutect2
- CDK10 | c.458A>G p.Y153C (on ENST00000353379 / NM_052988.5; = p.Y82C on NM_052987.4) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1191727848; called by muse, mutect2, varscan2
- CEACAM20 | c.1741C>T p.L581F | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1246648795; called by muse, mutect2
- CLIC3 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65406846; called by muse, mutect2, varscan2
- COL1A2 | c.2329C>T p.R777C | Missense Mutation (SNP) | VAF 123/719 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs779108678, COSV51961827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCHS1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 55/476 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as rs775163740, COSV55033305; called by muse, mutect2, varscan2
- DLAT | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs1198304536; called by muse, mutect2, varscan2
- DNAH3 | c.9854C>T p.T3285M | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs765782793, COSV54545204; called by muse, mutect2, varscan2
- DPYSL5 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as rs753410511, COSV56511910, COSV56512276; called by muse, mutect2, varscan2
- EIF5A | c.276T>G p.I92M | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV59751130; called by muse, mutect2
- GABRB3 | c.1007C>A p.P336H | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV54678375; called by muse, mutect2, varscan2
- LAMA4 | c.3308G>A p.R1103H (on ENST00000230538 / NM_001105206.3; = p.R1096H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs782568532; called by muse, mutect2, varscan2
- LIMCH1 | c.2948G>A p.R983Q | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs369048287; called by muse, mutect2
- LPP | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); catalogued as rs141444221; called by muse, mutect2
- MAP2K2 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755854200; called by muse, mutect2, varscan2
- MYH7 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 66/811 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1036184671, COSV62519869; ClinVar: uncertain significance; called by muse, mutect2
- NRXN3 | c.2744G>A p.G915D (on ENST00000335750 / NM_001330195.2; = p.G542D on NM_004796.6) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV59715827; called by muse, mutect2, varscan2
- NTN3 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 77/340 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746016178, COSV99564550; called by muse, mutect2, varscan2
- PNLIPRP1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs116575931, COSV100724521, COSV62613062; called by muse, mutect2, varscan2
- PTBP2 | c.1202A>G p.N401S (on ENST00000426398 / NM_001300986.2; = p.N393S on NM_021190.4) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772949179; called by muse, mutect2
- RAB29 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 86/416 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.058); catalogued as rs779129700; called by muse, mutect2, varscan2
- RAPGEF6 | c.4675G>T p.V1559L | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV57242575; called by muse, mutect2, varscan2
- RBPJL | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs146643791; called by muse, mutect2
- RELN | c.1242A>T p.E414D | Missense Mutation (SNP) | VAF 93/578 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.931); catalogued as rs909645591, COSV59008857; called by muse, mutect2, varscan2
- SHBG | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs373769356, CM147898; called by muse, mutect2, varscan2
- SKI | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 50/456 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs780767199; called by muse, mutect2, varscan2
- SLC12A9 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.238); catalogued as rs200048794; called by muse, mutect2, varscan2
- TBX20 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 54/579 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as rs1299828686; called by muse, mutect2
- TMCC1 | c.1457A>G p.H486R (on ENST00000393238 / NM_001349268.2; = p.H162R on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1442105453; called by muse, mutect2, varscan2
- TMEM132A | c.1519G>A p.E507K (on ENST00000453848 / NM_178031.3; = p.E508K on NM_017870.4) | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as rs953558337; called by muse, mutect2, varscan2
- TRPV3 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 58/521 reads (11%) | catalogued as rs766623921, COSV56795387; called by muse, mutect2, varscan2
- URB1 | c.3686C>T p.A1229V | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1266076162, COSV66960890; called by muse, mutect2
- XIAP | c.580A>G p.I194V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746580444; called by muse, mutect2, varscan2
- ZIC1 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV51550276; called by muse, mutect2
- ZNF689 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as rs771853380; called by muse, mutect2
- ZNF91 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 48/472 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs202143348; called by muse, mutect2
- ADAMTS20 | c.1158C>G p.S386R | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- AJM1 | c.2212C>T p.R738C | Missense Mutation (SNP) | VAF 74/334 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AMN | c.44-3dup | Splice Region (INS) | VAF 62/566 reads (11%) | called by mutect2, pindel, varscan2
- APOL5 | c.1265G>A p.R422K | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ARHGAP35 | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AVPR1A | c.104T>A p.L35H | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- C1orf167 | c.3087_3089del p.Q1029_A1030delinsH | In Frame Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel
- CCNB1 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CCND2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCNH | c.933+5G>A | Splice Region (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- CD5L | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKN2A | c.105_116del p.L37_A40del | In Frame Del (DEL) | VAF 71/260 reads (27%) | called by mutect2, pindel, varscan2
- COG3 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.89); PolyPhen benign (0.057); called by muse, mutect2
- COL6A5 | c.2491G>C p.D831H | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2
- DTWD2 | c.167G>T p.W56L | Missense Mutation (SNP) | VAF 46/429 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EFR3A | c.732_742del p.A245Efs*4 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | called by mutect2, pindel, varscan2
- EIF3E | c.1100C>G p.A367G | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.685); called by muse, mutect2
- EPHA2 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 59/507 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPHX2 | c.1214T>G p.F405C | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ETNPPL | c.1124A>G p.H375R | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EXD3 | c.1640A>T p.E547V | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- F11 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT1 | c.1460C>A p.A487D | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPAT4 | c.789dup p.A264Cfs*28 | Frame Shift Ins (INS) | VAF 18/145 reads (12%) | called by mutect2, pindel, varscan2
- HAT1 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HELZ | c.2381A>T p.D794V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYOU1 | c.2918A>T p.E973V | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- IFT52 | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 27/334 reads (8%) | called by muse, mutect2
- INPP5F | c.653A>G p.D218G | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2
- IRS1 | c.2387G>A p.G796D | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); called by muse, mutect2
- KDM6B | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- LST1 | c.250A>C p.K84Q | Missense Mutation (SNP) | VAF 63/568 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC22 | c.4828T>C p.S1610P | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MX1 | c.1868A>G p.K623R | Missense Mutation (SNP) | VAF 16/508 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2
- MYH9 | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 78/342 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- NEK3 | c.1275C>A p.S425R | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- NMUR2 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- PCLO | c.10996C>G p.P3666A | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2
- PPP4R4 | c.1549A>C p.I517L | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCA | c.918G>C p.E306D | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2
- QSER1 | c.5152G>C p.D1718H (on ENST00000399302; = p.D1847H on NM_001076786.3) | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- RBP3 | c.3056T>C p.I1019T | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RPS6KA3 | c.1567A>G p.I523V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC15A5 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 113/457 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- SLC2A13 | c.18C>G p.S6R | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- SLC4A10 | c.1814G>A p.C605Y (on ENST00000446997 / NM_001354461.2; = p.C575Y on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- SORBS2 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by mutect2, varscan2
- SYN3 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TDRKH | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- TENM3 | c.1685G>A p.G562D | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM100 | c.254T>A p.I85N | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOX3 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TRPV3 | c.434_447del p.L145Pfs*2 | Frame Shift Del (DEL) | VAF 23/221 reads (10%) | called by mutect2, pindel, varscan2
- TSPOAP1 | c.3654G>A p.M1218I | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.23749A>C p.T7917P (on ENST00000591111; = p.T6990P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- UBR4 | c.9691C>T p.H3231Y | Missense Mutation (SNP) | VAF 61/594 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- USP8 | c.2753A>G p.N918S | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- VRTN | c.1075del p.T359Pfs*16 | Frame Shift Del (DEL) | VAF 48/198 reads (24%) | called by mutect2, pindel, varscan2
- WDR11 | c.468C>A p.S156R | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF286A | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.291); called by muse, mutect2
- ZNF610 | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.192); called by muse, mutect2
- ZNF804B | c.3361A>G p.T1121A | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AL031777.2 | c.255G>A p.Q85= | Silent (SNP) | VAF 33/401 reads (8%) | catalogued as rs977788556; called by muse, mutect2
- AL031777.2 | c.144G>C p.A48= | Silent (SNP) | VAF 50/393 reads (13%) | catalogued as rs764565974; called by muse, mutect2, varscan2
- CCDC151 | c.513G>T p.V171= | Silent (SNP) | VAF 31/341 reads (9%) | called by muse, mutect2
- CENPI | c.1629A>G p.L543= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs759108988; called by muse, mutect2, varscan2
- CFAP53 | c.1410C>T p.R470= | Silent (SNP) | VAF 53/376 reads (14%) | called by muse, mutect2, varscan2
- CNKSR1 | c.1825C>A p.R609= (on ENST00000374253 / NM_001297647.2; = p.R602= on NM_006314.3) | Silent (SNP) | VAF 21/244 reads (9%) | called by muse, mutect2
- DLK1 | c.84G>A p.P28= | Silent (SNP) | VAF 32/294 reads (11%) | catalogued as rs771292634; called by muse, mutect2, varscan2
- FAM171B | c.927C>A p.V309= | Silent (SNP) | VAF 19/281 reads (7%) | catalogued as COSV100488925; called by muse, mutect2
- FAT4 | c.12936G>T p.G4312= | Silent (SNP) | VAF 21/165 reads (13%) | catalogued as COSV58687381; called by muse, mutect2, varscan2
- FSIP2 | c.1383C>A p.T461= | Silent (SNP) | VAF 11/197 reads (6%) | catalogued as COSV100555324; called by muse, mutect2
- HELZ2 | c.4098C>T p.C1366= (on ENST00000467148 / NM_001037335.2; = p.C797= on NM_033405.3) | Silent (SNP) | VAF 24/228 reads (11%) | catalogued as rs777924304, COSV101427550; called by muse, varscan2
- IGSF11 | c.1047A>T p.S349= (on ENST00000393775 / NM_001015887.3; = p.S348= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/548 reads (9%) | called by muse, mutect2
- INCENP | c.366G>A p.R122= | Silent (SNP) | VAF 45/565 reads (8%) | called by muse, mutect2
- ITPRID1 | c.90G>A p.A30= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as rs771087429; called by muse, mutect2, varscan2
- LY75 | c.3396G>A p.L1132= | Silent (SNP) | VAF 69/537 reads (13%) | called by muse, mutect2, varscan2
- MAP4K5 | c.483G>A p.V161= | Silent (SNP) | VAF 29/316 reads (9%) | catalogued as rs992549326; called by muse, mutect2
- NELFCD | c.1755G>T p.T585= (on ENST00000602795; = p.T567= on NM_198976.4) | Silent (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2
- NLRP13 | c.936C>A p.G312= | Silent (SNP) | VAF 19/219 reads (9%) | called by muse, mutect2
- OR8D4 | c.351C>T p.A117= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs1478441428, COSV58431094; called by muse, mutect2, varscan2
- PLPPR4 | c.1521C>T p.G507= | Silent (SNP) | VAF 26/298 reads (9%) | catalogued as rs916220419, COSV64564738; called by muse, mutect2
- PRDM11 | c.1095C>T p.I365= (on ENST00000530656 / NM_001359633.1; = p.I331= on NM_001256695.1) | Silent (SNP) | VAF 24/364 reads (7%) | catalogued as COSV99771136; called by muse, mutect2
- PSMA7 | c.408C>T p.F136= | Silent (SNP) | VAF 17/219 reads (8%) | catalogued as rs372487613; called by muse, mutect2
- PTCD1 | c.1605C>T p.D535= | Silent (SNP) | VAF 150/926 reads (16%) | catalogued as COSV52860737; called by muse, mutect2, varscan2
- SPAG5 | c.3225T>C p.L1075= | Silent (SNP) | VAF 31/245 reads (13%) | called by muse, mutect2, varscan2
- TG | c.7161C>T p.G2387= | Silent (SNP) | VAF 34/402 reads (8%) | catalogued as rs766209120, COSV55084864; called by muse, mutect2
- TMPRSS6 | c.717C>T p.H239= | Silent (SNP) | VAF 100/394 reads (25%) | catalogued as rs770614371; called by muse, mutect2, varscan2
- ZNF700 | c.57G>A p.R19= | Silent (SNP) | VAF 53/313 reads (17%) | called by muse, mutect2, varscan2
- ACBD4 | chr17:45143530 G>A | 3'Flank (SNP) | VAF 27/291 reads (9%) | catalogued as COSV58851172; called by muse, mutect2
- ADD3-AS1 | chr10:109941663 C>T | 3'Flank (SNP) | VAF 15/147 reads (10%) | catalogued as rs774983534; called by muse, mutect2, varscan2
- ANKRD26P1 | n.1638A>T | RNA (SNP) | VAF 10/76 reads (13%) | called by mutect2, varscan2
- DUOXA1 | chr15:45117978 C>T | 3'Flank (SNP) | VAF 19/201 reads (9%) | called by muse, mutect2
- EIF4G1 | c.537+29T>G | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- LINC01556 | n.199T>C | RNA (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- LINC02868 | n.76C>G | RNA (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- MIR124-2 | chr8:64378171 C>T | 5'Flank (SNP) | VAF 15/191 reads (8%) | called by muse, mutect2
- POMZP3 | c.228-111G>A | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- PREP | c.-10C>A | 5'UTR (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- SHISA5 | c.*271_*287del | 3'UTR (DEL) | VAF 30/204 reads (15%) | called by mutect2, pindel
